TCGA case TCGA-UB-A7MA — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: UCSF. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/10179efc-a091-4119-8ec2-30db6269d674

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 62 years; Vital status: Alive.

Diagnoses (5)
1. Combined hepatocellular carcinoma and cholangiocarcinoma (the primary disease): ICD-O-3 morphology code: 8180/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 62.5 years (22,843 days); Year of diagnosis: 2013; AJCC staging edition: 7th; AJCC pathologic T: T2b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Child pugh classification: A; Ishak fibrosis score: 0 - No Fibrosis.
   Pathology details: Consistent pathology review: Yes; Vascular invasion present: Yes; Vascular invasion type: Micro.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Gemcitabine; Days to treatment start: 60 days; Days to treatment end: 207 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemoembolization; Therapeutic agents: Mitomycin; Days to treatment start: 294 days; Embolic agent: Other.
   Treatment given: Treatment type: Ablation, Radiofrequency; Days to treatment start: 295 days; Number of cycles: 1; Lesions treated number: 4.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Sorafenib + Temsirolimus; Days to treatment start: 485 days (1.3 years); Treatment outcome: Treatment Ongoing; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Combined hepatocellular carcinoma and cholangiocarcinoma), site: Liver. Age at diagnosis: 63.1 years (23,064 days); Days to diagnosis: 221 days; Prior treatment: Yes.
   Treatment given: Treatment type: Ablation or Embolization, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Organ Transplantation to Liver, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.
3. Recurrence of diagnosis 1 (Combined hepatocellular carcinoma and cholangiocarcinoma), site: Lung, NOS. Age at diagnosis: 63.6 years (23,238 days); Days to diagnosis: 395 days (1.1 years); Prior treatment: Yes.
   Recorded as not given: Ablation or Embolization, NOS, for recurrent disease; Organ Transplantation to Liver, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.
4. Recurrence of diagnosis 1 (Combined hepatocellular carcinoma and cholangiocarcinoma), site: Lung, NOS. Age at diagnosis: 63.8 years (23,292 days); Days to diagnosis: 449 days (1.2 years); Prior treatment: Yes.
   Recorded as not given: Ablation or Embolization, NOS, for recurrent disease; Organ Transplantation to Liver, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.
5. Recurrence of diagnosis 1 (Combined hepatocellular carcinoma and cholangiocarcinoma), site: Liver. Age at diagnosis: 63.8 years (23,321 days); Days to diagnosis: 478 days (1.3 years); Prior treatment: Yes.
   Recorded as not given: Ablation or Embolization, NOS, for recurrent disease; Organ Transplantation to Liver, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (8 entries)
- Day 221 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Local; Progression or recurrence anatomic site: Liver; Days to recurrence: 221 days.
- Day 395 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS; Days to recurrence: 395 days (1.1 years).
- Day 449 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS; Days to recurrence: 449 days (1.2 years).
- Days to follow up: 455 days (1.2 years); Disease response: With Tumor.
- Day 478 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Local; Progression or recurrence anatomic site: Liver; Days to recurrence: 478 days (1.3 years).
- Days to follow up: 535 days (1.5 years); Disease response: With Tumor.
- ECOG performance status: 0.
- Follow-up contact recording only the day: day 848.

Molecular and laboratory tests
- Creatinine 0.7 mg/dL [Blood test normal range lower: 0.4; Blood test normal range upper: 0.9].
- Alpha Fetoprotein 2008 ng/mL [Blood test normal range lower: 0; Blood test normal range upper: 8].
- Total Bilirubin 1.2 mg/dL [Blood test normal range lower: 0; Blood test normal range upper: 1].
- Prothrombin time (INR, as labelled on the TCGA clinical form) 0.9 [Blood test normal range lower: 0.9; Blood test normal range upper: 1.2].
- Platelets 600 (unit not recorded by GDC) [Blood test normal range lower: 140; Blood test normal range upper: 450].
- Albumin 4 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.4; Blood test normal range upper: 5].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 85 kg; Height: 165 cm; BMI: 31.2.
- Timepoint category: Prior to Diagnosis; Viral hepatitis serology tests: Hepatitis B Surface Antigen / HBV Core Antibody / Hepatitis C Antibody.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-UB-A7MA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 500 mg.
  Slide TCGA-UB-A7MA-01A-01-TSA: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-UB-A7MA-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-UB-A7MA-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: With tumor; Histologic diagnosis: Hepatocholangiocarcinoma (Mixed); Definitive surgical procedure: Extended Lobectomy.
- History hepato carcinoma risk factors: No History of Primary Risk Factors.
- Viral hepatitis serologies: Viral hepatitis serology: Hepatitis  C Antibody; Viral hepatitis serology: Hepatitis B Surface Antigen; Viral hepatitis serology: HBV Core Antibody.
- Follow-up form 1: Lost to follow-up: No; Tumor status: With tumor.
- Drug treatment 1: Treatment best response: Clinical Progressive Disease.
- Ablations, Ablation, Ablation treatments: Ablation performed indicator: Yes.
- Ablations, Ablation, Ablation treatments, Ablation treatment: Ablation type: Radiofrequency Ablation; Treatment cycles count: 1; Lesions count: 4.
- Ablations, Ablation, Embolization treatments: Embolization performed indicator: Yes.
- Ablations, Ablation, Embolization treatments, Embolization treatment: Embolization therapy drug name: Mitomycin C; Embolizing agent utilized: Ethiodol.

GDC annotations on this case (curator notes; quoted as recorded):
- General: Case originally accepted in the liver study, but is a cholongio-liver mix. This case will not be removed or change studies, but will be analyzed in the CHOL study and not in the LIHC study.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 848 days; disease-specific survival: no event (censored), 848 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 221 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-UB-A7MA-01A-11D-A33P-01): tumor purity 0.73, ploidy 4.29, whole-genome doublings 2.
